Somatic mutation profile of tumor specimen 0DN51O from CCDI case PBCBCD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.8 years (4,669 days).
Specimen 0DN51O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7e5a865-20b3-4405-884a-d1b63dce457e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN51I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a2e01cb-d112-4cd5-b854-97e90705cce6

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, Intron 2, Splice Site 2, 5'Flank 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 245/667 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157030312, COSV50547633; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 379/920 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.493-2A>G p.X165_splice | Splice Site (SNP) | VAF 306/413 reads (74%) | catalogued as rs587781784, CS075218, COSV64297091, COSV64308401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCAF4L2 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 368/750 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60478562; called by muse, mutect2, varscan2
- DDX3X | c.1483G>T p.V495L (on ENST00000399959; = p.V496L on NM_001356.5) | Missense Mutation (SNP) | VAF 392/440 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV67863150; called by muse, mutect2, varscan2
- GPR137B | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 285/1153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777123792, COSV63991523; called by muse, mutect2, varscan2
- GRPEL1 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 539/1393 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV53827753; called by muse, mutect2, varscan2
- KDM6A | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 254/271 reads (94%) | catalogued as COSV65039013, COSV65048375; called by muse, mutect2, varscan2
- LILRA2 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 165/395 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52196295; called by muse, mutect2, varscan2
- OR6Y1 | c.961G>T p.G321W | Missense Mutation (SNP) | VAF 323/1322 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs1477992982, COSV56930654, COSV56931359; called by muse, mutect2, varscan2
- TRPC6 | c.1636A>G p.M546V | Missense Mutation (SNP) | VAF 160/1232 reads (13%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.472); catalogued as rs1241043006; called by muse, mutect2, varscan2
- UBL4B | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 214/534 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773711040; called by muse, mutect2, varscan2
- ADAMTS19 | c.2737A>T p.N913Y | Missense Mutation (SNP) | VAF 499/1215 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AHNAK | c.16001T>C p.V5334A | Missense Mutation (SNP) | VAF 268/595 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CIZ1 | c.2487+6C>T | Splice Region (SNP) | VAF 208/444 reads (47%) | called by muse, mutect2, varscan2
- CRB1 | c.215A>T p.D72V | Missense Mutation (SNP) | VAF 554/1850 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ITGAM | c.2509-2A>G p.X837_splice (on ENST00000648685 / NM_001145808.2; = p.X836_splice on NM_000632.4) | Splice Site (SNP) | VAF 22/544 reads (4%) | called by muse, mutect2
- OR10H4 | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 22/830 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2
- PTPRQ | c.5565A>T p.K1855N (on ENST00000616559; = p.K1813N on NM_001145026.2) | Missense Mutation (SNP) | VAF 573/1399 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RNF217 | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 150/317 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- SCGB1C1 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 299/850 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CNBD2 | c.573C>T p.D191= | Silent (SNP) | VAF 399/983 reads (41%) | catalogued as rs371946971; called by muse, mutect2, varscan2
- CUEDC2 | c.789G>T p.V263= | Silent (SNP) | VAF 36/521 reads (7%) | called by muse, mutect2
- DNAH3 | c.9774C>T p.T3258= | Silent (SNP) | VAF 302/761 reads (40%) | catalogued as rs747087879; called by muse, mutect2, varscan2
- DUS1L | c.480C>T p.Y160= | Silent (SNP) | VAF 378/898 reads (42%) | catalogued as rs202183417; called by muse, mutect2, varscan2
- NCOR2 | c.6024G>A p.P2008= | Silent (SNP) | VAF 316/756 reads (42%) | catalogued as rs745657498, COSV62296052; called by muse, mutect2, varscan2
- NID1 | c.342C>T p.T114= | Silent (SNP) | VAF 365/1167 reads (31%) | catalogued as rs768178715, COSV99938236; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPAP1 | c.558G>A p.S186= | Silent (SNP) | VAF 224/500 reads (45%) | catalogued as rs139317336; called by muse, mutect2, varscan2
- TMEM245 | c.2544G>A p.T848= | Silent (SNP) | VAF 732/794 reads (92%) | catalogued as rs766218648, COSV65822355; called by mutect2, varscan2
- ZNF354B | c.360A>T p.I120= | Silent (SNP) | VAF 511/1197 reads (43%) | catalogued as rs1027081697; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415182 C>T | 5'Flank (SNP) | VAF 220/534 reads (41%) | catalogued as rs150014655; called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- PXDNL | c.4147-46T>A | Intron (SNP) | VAF 280/628 reads (45%) | called by muse, mutect2, varscan2
